Somatic mutation profile of tumor specimen MMRF_1723_1_BM_CD138pos (aliquot MMRF_1723_1_BM_CD138pos_T1_KBS5U_L06439) from MMRF case MMRF_1723, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.6 years (25,417 days).
Specimen MMRF_1723_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 735e5925-3d57-4161-a770-ddf0fa1030e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1723_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1723_1_PB_Whole_C2_KBS5U_L06482; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cc4f47c-67f1-4b3f-8597-de90a8280f89

The open-access MAF lists 150 somatic variants for this specimen: 53 protein-altering or splice-affecting, 23 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 39, Silent 23, Intron 15, 5'UTR 8, 3'Flank 7, Nonsense Mutation 4, Frame Shift Del 4, RNA 4, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD6 | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as rs1233737886; called by muse, mutect2, varscan2
- ACVR2A | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1381913043, COSV54018779, COSV54020026; called by muse, mutect2, varscan2
- ALKBH6 | c.7G>A p.E3K (on ENST00000252984 / NM_001297701.2; = p.E31K on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/331 reads (71%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV99431325; called by muse, mutect2, varscan2
- ANK3 | c.2975C>T p.A992V (on ENST00000280772 / NM_001320874.2; = p.A126V on NM_001149.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55075206; called by muse, mutect2, varscan2
- CRYGD | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs375824046, CM103081; called by muse, varscan2
- H2AC1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as COSV51237141; called by muse, mutect2, varscan2
- IGHD5-24 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 10/11 reads (91%) | catalogued as rs1218806520; called by muse, mutect2, varscan2
- IGLL5 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1338923337, COSV104440281; called by muse, mutect2
- IGLV4-60 | c.321T>A p.D107E | Missense Mutation (SNP) | VAF 85/152 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs755023305; called by muse, mutect2, varscan2
- KIF19 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100739256; called by muse, mutect2, varscan2
- LPAR1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.577); catalogued as rs748796192, COSV62688148; called by muse, mutect2, varscan2
- PGR | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1175582391, COSV54804760, COSV99678432; called by muse, mutect2, varscan2
- RBM28 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746002917, COSV56162615, COSV56163812; called by muse, mutect2, varscan2
- SECISBP2 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 195/285 reads (68%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.823); catalogued as rs1564300040; called by muse, mutect2, varscan2
- SHROOM2 | c.3259G>A p.V1087M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745337866, COSV66607450; called by muse, mutect2, varscan2
- TENM4 | c.4516G>A p.V1506I | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.202); catalogued as rs550019697, COSV99581049; called by muse, mutect2, varscan2
- TMEM132B | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs747888388, COSV54757309; called by muse, mutect2, varscan2
- TNKS1BP1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 135/208 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs748049254; called by muse, mutect2, varscan2
- TRPS1 | c.935C>T p.S312L (on ENST00000220888 / NM_001330599.2; = p.S325L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1212301901, COSV55252290; called by muse, mutect2, varscan2
- ZBTB7A | c.614_625del p.A205_A208del | In Frame Del (DEL) | VAF 86/204 reads (42%) | catalogued as rs759684209; called by mutect2, varscan2
- ZFHX2 | c.5950G>A p.G1984R | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs777697799; called by muse, mutect2, varscan2
- ZSCAN22 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 112/416 reads (27%) | catalogued as COSV100308387; called by muse, mutect2, varscan2
- AP2A1 | c.2694del p.M899Wfs*58 | Frame Shift Del (DEL) | VAF 79/378 reads (21%) | called by mutect2, pindel, varscan2
- BHLHE41 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- C2orf49 | c.317del p.G106Efs*8 | Frame Shift Del (DEL) | VAF 90/195 reads (46%) | called by mutect2, pindel, varscan2
- DCLRE1B | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- DGKH | c.2063C>G p.A688G | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSG4 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTNBP1 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM228B | c.681G>T p.R227S | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- IFI16 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- IGHA2 | c.314_323del p.P105Hfs*19 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- IGHV1-69D | c.296A>C p.Y99S | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IGLV4-60 | c.153del p.Y52Tfs*17 | Frame Shift Del (DEL) | VAF 86/205 reads (42%) | called by mutect2, pindel, varscan2
- ITPR1 | c.4977T>G p.H1659Q (on ENST00000354582; = p.H1644Q on NM_002222.7) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- JUNB | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA2012 | c.1960A>C p.S654R | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- LRRN3 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRTM4 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- MPDZ | c.5812G>C p.G1938R (on ENST00000319217 / NM_001330637.2; = p.G1909R on NM_003829.5) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTAP | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- MYO15A | c.3889C>A p.L1297I | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PRPF8 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN6 | c.1515C>G p.Y505* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- SHC2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- SIK3 | c.3922G>A p.G1308R (on ENST00000445177 / NM_001366686.2; = p.G1266R on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC4A11 | c.1607G>T p.S536I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- STAG1 | c.768T>G p.N256K | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SYDE2 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TENM3 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TRAF3 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 79/81 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASL | c.848C>G p.S283* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- ZNF154 | c.86dup p.L30Sfs*3 | Frame Shift Ins (INS) | VAF 90/398 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.633G>A p.A211= | Silent (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2
- ADGRB3 | c.846T>C p.A282= | Silent (SNP) | VAF 59/145 reads (41%) | called by muse, mutect2, varscan2
- AP1M2 | c.747C>T p.N249= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs368763595; called by muse, mutect2, varscan2
- CACNA2D4 | c.2958C>T p.Y986= | Silent (SNP) | VAF 93/228 reads (41%) | catalogued as rs142964907; called by muse, mutect2, varscan2
- COL5A3 | c.4533C>T p.G1511= | Silent (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- DLG4 | c.1713G>A p.R571= (on ENST00000399506 / NM_001321075.3; = p.R614= on NM_001365.4) | Silent (SNP) | VAF 70/157 reads (45%) | called by muse, mutect2, varscan2
- FABP5 | c.76C>T p.L26= | Silent (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- FKBP4 | c.564C>T p.L188= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, varscan2
- FSCN3 | c.231G>A p.E77= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs748609905; called by muse, mutect2, varscan2
- GLYATL2 | c.426G>A p.K142= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV54849858; called by muse, mutect2
- GNG14 | c.255C>T p.D85= | Silent (SNP) | VAF 23/281 reads (8%) | called by muse, mutect2
- IGHA1 | c.192C>T p.Y64= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as rs765798878; called by muse, mutect2, varscan2
- IGHV2-70D | c.54A>G p.L18= | Silent (SNP) | VAF 42/52 reads (81%) | called by muse, varscan2
- IGLV3-1 | c.102A>G p.G34= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as rs185369291; called by muse, mutect2, varscan2
- MYBPC3 | c.87C>T p.F29= | Silent (SNP) | VAF 102/154 reads (66%) | catalogued as rs764557472; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.5577G>A p.A1859= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as rs745484350; called by muse, mutect2, varscan2
- OR5H2 | c.54T>C p.V18= | Silent (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- PTPN22 | c.330C>A p.L110= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- SERPINB10 | c.357G>A p.T119= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as rs201911253, COSV53075305; called by muse, mutect2, varscan2
- SIGLEC12 | c.255G>A p.V85= | Silent (SNP) | VAF 81/360 reads (23%) | catalogued as COSV99389523; called by muse, mutect2
- SMCO1 | c.102C>T p.F34= | Silent (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- TMEM138 | c.96A>G p.Q32= | Silent (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
- WFDC1 | c.48C>T p.I16= | Silent (SNP) | VAF 60/63 reads (95%) | catalogued as rs886724233; called by muse, mutect2, varscan2
- ABHD18 | c.*2615C>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- AC073316.1 | n.537C>T | RNA (SNP) | VAF 26/102 reads (25%) | catalogued as rs565181454; called by muse, mutect2
- AC116366.2 | c.-637-10158T>G | Intron (SNP) | VAF 77/240 reads (32%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27196236 A>G | 3'Flank (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2
- ADAMTS12 | c.*1040A>C | 3'UTR (SNP) | VAF 20/90 reads (22%) | catalogued as COSV61265319; called by muse, mutect2, varscan2
- AK5 | c.699+15913C>T | Intron (SNP) | VAF 62/120 reads (52%) | catalogued as rs760595956, COSV100481593; called by muse, mutect2, varscan2
- AKAP7 | c.*1170C>T | 3'UTR (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- ARF1 | c.148+22A>C | Intron (SNP) | VAF 104/171 reads (61%) | called by muse, mutect2, varscan2
- ARL14EP | c.-63-2748_-63-2747del | Intron (DEL) | VAF 6/72 reads (8%) | catalogued as rs1491113550, COSV56342316; called by pindel, varscan2*
- ATP2B4 | c.*2525T>C | 3'UTR (SNP) | VAF 40/131 reads (31%) | called by muse, mutect2, varscan2
- BMP6 | c.*931_*961del | 3'UTR (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- BMP6 | c.*1229A>G | 3'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- BTG2 | c.*1655C>T | 3'UTR (SNP) | VAF 89/170 reads (52%) | called by muse, mutect2, varscan2
- C19orf25 | c.131-301G>A | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as rs528160264; called by muse, mutect2, varscan2
- C6orf226 | c.*76T>C | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- CACNB4 | c.148-88031del | Intron (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CCDC162P | n.2849G>A | RNA (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- CCNG2 | c.*1058A>G | 3'UTR (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- CDC42EP3 | c.*3026C>A | 3'UTR (SNP) | VAF 16/57 reads (28%) | catalogued as rs546739196; called by muse, mutect2, varscan2
- COX6B2 | chr19:55354759 C>T | 5'Flank (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- CSPG5 | c.-1121G>A | 5'UTR (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.*2802T>C | 3'UTR (SNP) | VAF 19/110 reads (17%) | catalogued as rs1055292423; called by muse, mutect2, varscan2
- DDX51 | c.519+98G>T | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- DIAPH2 | c.*3815C>T | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*68G>A | 3'UTR (SNP) | VAF 26/78 reads (33%) | catalogued as rs920687542, COSV65370631; called by muse, mutect2, varscan2
- DPH6 | c.*1159T>C | 3'UTR (SNP) | VAF 98/134 reads (73%) | called by muse, mutect2, varscan2
- ERLIN1 | chr10:100151527 G>A | 3'Flank (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- ETS1 | c.-80G>A | 5'UTR (SNP) | VAF 75/222 reads (34%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.*9G>C | 3'UTR (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- FAM162B | c.-94G>A | 5'UTR (SNP) | VAF 13/50 reads (26%) | catalogued as rs1477362063; called by muse, mutect2, varscan2
- FAM189A1 | c.*1493A>G | 3'UTR (SNP) | VAF 38/210 reads (18%) | catalogued as rs545961687; called by muse, mutect2, varscan2
- FRG1GP | n.507A>G | RNA (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- GPS2 | c.95-55A>C | Intron (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- H2BC21 | c.*995A>C | 3'UTR (SNP) | VAF 80/119 reads (67%) | called by muse, mutect2, varscan2
- HINT1 | chr5:131158977 G>A | 3'Flank (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- HINT3 | c.*712T>A | 3'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- IGLL5 | c.-37C>T | 5'UTR (SNP) | VAF 41/66 reads (62%) | catalogued as rs138573360, COSV101597192; called by muse, mutect2, varscan2
- KBTBD4 | c.*523C>T | 3'UTR (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128920592 G>T | 3'Flank (SNP) | VAF 83/130 reads (64%) | called by muse, mutect2, varscan2
- KLHL1 | c.-252C>T | 5'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- LAMB3 | c.2358+58C>A | Intron (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- LONRF3 | c.*295A>T | 3'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- LRCH2 | c.*851T>G | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- MFAP3L | c.*2593C>T | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- MYO1F | c.*17C>A | 3'UTR (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- NAALADL2 | c.*800G>T | 3'UTR (SNP) | VAF 56/122 reads (46%) | catalogued as rs1414192379; called by muse, mutect2, varscan2
- NEURL4 | c.*463C>T | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, varscan2
- NFIA | c.*2690del | 3'UTR (DEL) | VAF 38/89 reads (43%) | catalogued as rs925114947; called by mutect2, varscan2
- NHLRC2 | c.*4084T>C | 3'UTR (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- NOVA1 | c.*123G>T | 3'UTR (SNP) | VAF 39/81 reads (48%) | catalogued as COSV99946363; called by muse, mutect2, varscan2
- PDCD6IPP2 | n.30C>G | RNA (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- PDIA3 | c.*629T>C | 3'UTR (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- PLSCR5 | c.-587G>T | 5'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- PTGDR | c.*348T>A | 3'UTR (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- QTRT2 | c.*777A>G | 3'UTR (SNP) | VAF 40/76 reads (53%) | catalogued as rs757870989; called by muse, mutect2, varscan2
- RHPN2 | c.*141T>G | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as COSV54277622; called by mutect2, varscan2
- RPL11 | c.6+140C>T | Intron (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- SDK1 | c.*2173A>G | 3'UTR (SNP) | VAF 10/177 reads (6%) | catalogued as COSV67389517; called by muse, mutect2
- SH3BGRL3 | c.216+31A>G | Intron (SNP) | VAF 48/108 reads (44%) | called by mutect2, varscan2
- SLC17A4 | c.*501G>A | 3'UTR (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50668875 C>T | 3'Flank (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- STAU2 | c.*984G>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- TMEM222 | c.540-64C>T | Intron (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- TMEM25 | c.383-87C>A | Intron (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2
- TMEM47 | c.*1776T>G | 3'UTR (SNP) | VAF 41/46 reads (89%) | called by muse, mutect2, varscan2
- TMOD1 | c.397+2207A>G | Intron (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.*1457T>C | 3'UTR (SNP) | VAF 41/72 reads (57%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115412451 T>A | 3'Flank (SNP) | VAF 6/132 reads (5%) | catalogued as COSV55239999; called by muse, mutect2
- VPS37C | c.*325G>A | 3'UTR (SNP) | VAF 7/169 reads (4%) | called by muse, mutect2
- ZFHX3 | c.*363T>C | 3'UTR (SNP) | VAF 30/32 reads (94%) | called by muse, mutect2, varscan2
- ZNF232 | c.-377C>T | 5'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- ZPLD1 | chr3:102478309 G>A | 3'Flank (SNP) | VAF 21/45 reads (47%) | catalogued as rs904123992; called by muse, mutect2, varscan2
- ZSCAN18 | c.554-117C>A | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as COSV53730759; called by muse, mutect2
- ZSCAN5B | c.-57G>A | 5'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
